Somatic mutation profile of tumor specimen 0DQQBS from CCDI case PBCEZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,161 days).
Specimen 0DQQBS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abdf9458-eae0-4ea7-b3d1-358c0abd71d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4da64c3-e62a-4f59-9fca-4dd6e591a29e

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 4, Silent 3, Intron 3, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP55 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 204/532 reads (38%) | catalogued as rs141458677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 193/436 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 153/463 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO7 | c.914C>T p.P305L (on ENST00000274979; = p.P251L on NM_001370694.2) | Missense Mutation (SNP) | VAF 53/664 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs374747359, COSV99239170; called by muse, mutect2
- CRACR2A | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as rs1382303956, COSV104414603; called by muse, mutect2, varscan2
- CSMD2 | c.10274C>T p.A3425V | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); catalogued as rs1248637022; called by muse, mutect2
- FSIP2 | c.18664G>A p.E6222K | Missense Mutation (SNP) | VAF 253/572 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100554465; called by muse, mutect2, varscan2
- GPR101 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 148/413 reads (36%) | catalogued as COSV99981397; called by muse, mutect2, varscan2
- HPS5 | c.3035T>C p.M1012T (on ENST00000349215 / NM_181507.2; = p.M898T on NM_007216.4) | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs762130841; called by muse, mutect2
- OR10G2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs750094846, COSV101606952; called by muse, mutect2, varscan2
- PCDHA2 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs371053543; called by muse, mutect2
- PPM1D | c.1547C>A p.S516* | Nonsense Mutation (SNP) | VAF 57/1015 reads (6%) | catalogued as rs772936724, COSV59955538, COSV59956876; called by muse, mutect2
- SYPL1 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); catalogued as rs757747921; called by muse, mutect2, varscan2
- CIZ1 | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- DYRK2 | c.764A>T p.N255I (on ENST00000344096 / NM_006482.3; = p.N182I on NM_003583.4) | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSD17B4 | c.1056_1057insG p.I353Dfs*39 (on ENST00000414835 / NM_001199291.3; = p.I328Dfs*39 on NM_000414.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 66/185 reads (36%) | called by mutect2, pindel*, varscan2
- LANCL3 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 12/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- METTL14 | c.765A>T p.R255S | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MMP27 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA5A | c.2480C>A p.S827Y | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TRIM51 | c.165C>A p.C55* | Nonsense Mutation (SNP) | VAF 17/569 reads (3%) | called by muse, mutect2
- CACNA1I | c.2544C>T p.F848= | Silent (SNP) | VAF 124/766 reads (16%) | catalogued as rs748286729; called by muse, mutect2, varscan2
- MMP12 | c.321C>T p.P107= | Silent (SNP) | VAF 35/295 reads (12%) | catalogued as rs781783954; called by muse, mutect2, varscan2
- RBM47 | c.321C>T p.D107= | Silent (SNP) | VAF 121/271 reads (45%) | catalogued as COSV55930240; called by muse, mutect2, varscan2
- ACTR1A | c.750+89G>A | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, varscan2
- FKBP6 | c.-118G>A | 5'UTR (SNP) | VAF 35/406 reads (9%) | catalogued as rs1563307892, COSV52723325; called by muse, mutect2
- MUC19 | n.20664-13T>C | Intron (SNP) | VAF 67/214 reads (31%) | called by muse, mutect2, varscan2
- YBX3 | c.574-68T>C | Intron (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
